Surgical pathology report (de-identified scan), TCGA case TCGA-77-A5G1, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-A5G1-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, Squamous
Cell NOS 8670/3
Site (R) Lung, lower lobe
C34.3

Histopathology Report

HISTORY

Lobectomy for carcinoma.

QAD 2/7/13

MACROSCOPIC

Six specimens are received.

1: The first specimen is labelled "R middle lobe, R lower lobe, R upper lobe" and consists of right middle and lower lobes with a small stapled wedge of upper lobe superiorly. The specimen measures 165 x 75 x 45 mm with the stapled wedge of upper lobe measuring 70 x 30 x 30 mm. There is a firm mass with overlying pleural adhesions at the apical aspect of the lower lobe, measuring 52 x 50 x 35 mm. On sectioning, the mass has a pale sclerotic appearance and is centrally cavitated. The cavity measures 12 mm across. The tumour extends to apparently involve the lateral pleural surface and it extends close to the pleura on the medial aspect. In this region it extends into a bronchus. There is possible involvement of the upper lobe but the tumour appears well clear of the stapled upper lobe resection margin. No other focal lesions are identified on sectioning and there are no other endobronchial lesions. [Bronchial and vascular resection margin, 1A; peribronchial lymph nodes, 1B; tumour with overlying pleura, 1C-1E; tumour and upper lobe resection margin, 1F; tumour and medial surface of lung, 1G; further section, 1H; tumour and proximal bronchus, 1I; random section of lung, 1J.]

2: The second specimen is labelled "upper lobe lymph node" and consists of two pieces of lymph node, 17 x 15 x 7 mm and 15 x 11 x 8 mm. [Each piece bisected and blocked in toto, 2A]

3: The third specimen is labelled "No. 11 lymph node" and consists of three pieces of tissue measuring 18 x 15 x 8 mm in aggregate. [Largest piece bisected and all tissue wrapped and blocked in toto, 3A]

4: The fourth specimen is labelled "No. 7 lymph node" and consists of pieces of fatty tissue measuring 45 x 30 x 15 mm in aggregate. [BIT, 4A-4B]

5: The fifth specimen is labelled "No. 8 lymph node" and consists of a piece of lymph node measuring 18 x 10 x 6 mm. [Bisected and BIT]

6: The sixth specimen is labelled "No. 9 lymph node" and consists of lymph node with surrounding fat measuring 35 x 16 x 8 mm. [Bisected and BIT]

MICROSCOPIC

1: Sections show a poorly differentiated squamous cell carcinoma with central cavitation. The cavitation appears to be due, at least in part, to vascular invasion by tumour which is present at multiple sites throughout the sections. Tumour invades into overlying parietal pleura but appears clear of the soft

[page 2 of 2]
tissue resection margin. No lymphatic invasion is seen, and peribronchial lymph nodes show no evidence of metastatic carcinoma. The upper lobe resection margin is well clear of malignancy. Proximally the tumour has a protruding endobronchial component but no in situ squamous carcinoma is found, and the bronchial resection margin is clear of malignancy. Focal perineural invasion is found towards the hilum. Lung parenchyma adjacent to the tumour shows organising pneumonia, while more distant lung parenchyma is unremarkable.

2: Sections show reactive lymphoid hyperplasia and several silicotic nodules, but there is no evidence of metastatic carcinoma.

3: Sections show small foci of metastatic squamous cell carcinoma in one of the lymph nodes.

4-6: Sections show reactive lymphoid hyperplasia and scattered silicotic nodules, but there is no evidence of metastatic carcinoma.

SUMMARY

Right middle and lower lobectomy, partial resection of right upper lobe and lymph node sampling:

Poorly differentiated squamous cell carcinoma of apical segment of right lower lobe, 52 mm in diameter.

Invasion of parietal pleura present, but soft tissue resection margin clear of malignancy.

Extensive vascular invasion present.

Focal perineural invasion present.

No lymphatic invasion found.

Metastatic carcinoma in no. 11 lymph node.

Pathological stage T3 N1.

Reported

T-28000 M-80703 P1-03000

	ANATOMICAL PATHOLOGY
	Report generated:

Source: NCI Genomic Data Commons file a3f4d32f-a64f-4ca7-b8f6-e9565e0bac82 (TCGA-77-A5G1.AC3570CB-4A07-4E52-AD77-2857BDF35C87.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).